Somatic mutation profile of cancer-model specimen HCM-CSHL-0731-C19-85M (3D Organoid, passage 4; aliquot HCM-CSHL-0731-C19-85M-01D-A82I-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0731-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 46.5 years (16,989 days).
Specimen HCM-CSHL-0731-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbb9c6e5-6ca5-4da7-a61d-935e7cdef046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0731-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0731-C19-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/693aca6f-85be-4e17-9567-70195f914ca1

The open-access MAF lists 104 somatic variants for this specimen: 80 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 22, Nonsense Mutation 7, Frame Shift Ins 2, Intron 1, Frame Shift Del 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 110/195 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 143/143 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100053399, COSV51014574; called by muse, mutect2, varscan2
- SMAD4 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 258/258 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377767346, CM994757, COSV61688013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 264/264 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARAF | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 827/828 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV51691221, COSV51692725, COSV51695605; called by muse, mutect2, varscan2
- ATP8B4 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 104/290 reads (36%) | catalogued as rs745514384, COSV52723280; called by muse, mutect2, varscan2
- C4orf50 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 280/694 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs370415223; called by muse, mutect2, varscan2
- CFAP99 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.143); catalogued as rs1183359514; called by muse, mutect2, varscan2
- CHST6 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 231/231 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1242731464, COSV59999424, COSV60000035; called by muse, mutect2, varscan2
- CRYBA2 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 26/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1479137928; called by muse, mutect2
- DMGDH | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs145775047; called by muse, mutect2, varscan2
- FOXE1 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 218/472 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as rs747177483, COSV64300771; called by muse, mutect2, varscan2
- GABRR1 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 135/271 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs778032711; called by muse, mutect2, varscan2
- GALNT18 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 228/481 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1370691131, COSV57144529; called by muse, mutect2, varscan2
- GRIK1 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs775408657, COSV58714756; called by muse, mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 161/402 reads (40%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 114/225 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373288568; called by muse, mutect2, varscan2
- KMT2D | c.6011A>G p.Q2004R | Missense Mutation (SNP) | VAF 148/457 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs1419446311; called by muse, mutect2, varscan2
- MAB21L2 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1328813338, COSV58261285; called by muse, mutect2
- MC2R | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 216/468 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs1190362792; called by muse, mutect2, varscan2
- MED12L | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768584576, COSV56395895; called by muse, mutect2, varscan2
- MGAM | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 148/335 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs368035457; called by muse, mutect2, varscan2
- MGME1 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 83/567 reads (15%) | catalogued as rs781005574; called by muse, mutect2, varscan2
- MYO1D | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 227/364 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757145678, COSV59012237; called by muse, mutect2, varscan2
- NALCN | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 144/299 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772251231, COSV51924258; called by muse, mutect2, varscan2
- NLGN4X | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 547/548 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338500760, COSV52004121, COSV99321427; called by muse, mutect2, varscan2
- OR4K1 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1489165075; called by muse, mutect2, varscan2
- PCBP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 247/508 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 136/415 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PDGFRB | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 37/353 reads (10%) | catalogued as rs1460983846, COSV55809598; called by muse, mutect2
- PNMA8B | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 55/531 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs1250491118; called by muse, mutect2, varscan2
- ROBO2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 151/232 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs746238322, COSV59903872; called by muse, mutect2, varscan2
- SELENOS | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776003975; called by muse, mutect2, varscan2
- SSX3 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 326/326 reads (100%) | catalogued as COSV53646006; called by muse, mutect2, varscan2
- TENM3 | c.4925C>T p.T1642M | Missense Mutation (SNP) | VAF 156/260 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375567039; called by muse, mutect2, varscan2
- THEMIS | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 292/573 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1403938167, COSV64069387; called by muse, mutect2, varscan2
- WWP2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 183/183 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs760137313; called by muse, mutect2, varscan2
- ZNF189 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 197/464 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs146668775; called by muse, mutect2, varscan2
- ZNF71 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 171/567 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60147238; called by muse, mutect2, varscan2
- ADGRG4 | c.5857G>T p.E1953* | Nonsense Mutation (SNP) | VAF 511/511 reads (100%) | called by muse, mutect2, varscan2
- APC | c.875dup p.L292Ffs*4 | Frame Shift Ins (INS) | VAF 119/232 reads (51%) | called by mutect2, pindel, varscan2
- APC | c.1979del p.N660Tfs*10 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- APOB | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 31/357 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); called by muse, mutect2
- ARHGEF17 | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 228/478 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD1 | c.1858G>T p.G620W | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- BRSK1 | c.2190C>G p.N730K | Missense Mutation (SNP) | VAF 241/346 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CIBAR2 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.923); called by muse, mutect2
- CLSPN | c.3336dup p.Q1113Tfs*12 | Frame Shift Ins (INS) | VAF 73/309 reads (24%) | called by mutect2, pindel, varscan2
- ESM1 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 111/324 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ESPNL | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 497/991 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- HMCN1 | c.13363G>T p.G4455C | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KAT6B | c.1692T>G p.S564R | Missense Mutation (SNP) | VAF 19/571 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2
- KCNU1 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 113/367 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, varscan2
- KLF5 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 233/469 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2D | c.2564T>C p.L855P | Missense Mutation (SNP) | VAF 15/534 reads (3%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- KPNB1 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- LRRTM1 | c.1556A>T p.E519V | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEB6 | c.726A>C p.Q242H | Missense Mutation (SNP) | VAF 629/629 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- METTL25 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 142/510 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- MYO18B | c.5656C>A p.Q1886K | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NCAM2 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCR2 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 28/620 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.036); called by muse, mutect2
- NPAT | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- OR2J3 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 381/381 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PELI2 | c.769A>C p.T257P | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PSD2 | c.1703A>G p.D568G | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- PTPRF | c.5135C>A p.T1712K | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RAB33B | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.054); called by muse, mutect2
- SEMA6A | c.2054A>G p.Q685R | Missense Mutation (SNP) | VAF 148/417 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMYD1 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 174/373 reads (47%) | called by muse, mutect2
- SNAI2 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 566/805 reads (70%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SPAG9 | c.3322T>A p.L1108M (on ENST00000262013 / NM_001130528.3; = p.L1094M on NM_003971.6) | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNGR2 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 276/467 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TNC | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 264/517 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.474_476del p.N158del | In Frame Del (DEL) | VAF 82/336 reads (24%) | called by pindel, varscan2
- WNT4 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 335/342 reads (98%) | SIFT tolerated (0.34); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- XIRP1 | c.3955C>A p.P1319T | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMYM4 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 55/163 reads (34%) | called by muse, mutect2, varscan2
- ZNF620 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 222/367 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADRA2B | c.276C>T p.D92= | Silent (SNP) | VAF 382/799 reads (48%) | catalogued as COSV69787260; called by muse, mutect2, varscan2
- ATG2A | c.570C>T p.A190= | Silent (SNP) | VAF 197/423 reads (47%) | catalogued as rs746073619; called by muse, mutect2, varscan2
- CD22 | c.1293G>T p.P431= | Silent (SNP) | VAF 77/246 reads (31%) | called by muse, mutect2, varscan2
- CDYL2 | c.33G>A p.R11= | Silent (SNP) | VAF 126/126 reads (100%) | called by muse, mutect2, varscan2
- DAZAP1 | c.822T>C p.F274= | Silent (SNP) | VAF 117/208 reads (56%) | catalogued as rs748239078; called by muse, mutect2, varscan2
- EFCAB6 | c.2250C>T p.F750= | Silent (SNP) | VAF 132/216 reads (61%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.2364G>T p.G788= | Silent (SNP) | VAF 37/548 reads (7%) | called by muse, mutect2
- FMNL3 | c.1131C>T p.N377= | Silent (SNP) | VAF 56/385 reads (15%) | catalogued as rs896259670, COSV53298823; called by muse, mutect2, varscan2
- IFNA21 | c.231C>T p.I77= | Silent (SNP) | VAF 225/475 reads (47%) | catalogued as COSV66518179, COSV66518646, COSV66518665; called by muse, mutect2, varscan2
- ITGA3 | c.2154C>T p.I718= | Silent (SNP) | VAF 233/414 reads (56%) | catalogued as rs998092599, COSV50310505; called by muse, mutect2, varscan2
- LYPD4 | c.252G>A p.S84= | Silent (SNP) | VAF 95/338 reads (28%) | catalogued as rs782100732; called by muse, mutect2, varscan2
- MATR3 | c.1291C>T p.L431= | Silent (SNP) | VAF 107/151 reads (71%) | called by muse, mutect2, varscan2
- NKX2-5 | c.771G>A p.P257= | Silent (SNP) | VAF 167/481 reads (35%) | called by muse, mutect2, varscan2
- NPIPB11 | c.2517C>T p.C839= | Silent (SNP) | VAF 102/674 reads (15%) | called by muse, mutect2, varscan2
- OR7D4 | c.399G>A p.T133= | Silent (SNP) | VAF 212/318 reads (67%) | catalogued as rs748510147, COSV100432846, COSV58071293; called by muse, mutect2, varscan2
- PDC | c.540C>G p.R180= | Silent (SNP) | VAF 27/358 reads (8%) | catalogued as rs766659596; called by muse, mutect2
- SDK2 | c.4323G>A p.E1441= | Silent (SNP) | VAF 33/709 reads (5%) | called by muse, mutect2
- SHOC2 | c.714T>C p.C238= | Silent (SNP) | VAF 116/196 reads (59%) | called by muse, mutect2, varscan2
- TOMM70 | c.114A>T p.R38= | Silent (SNP) | VAF 201/618 reads (33%) | called by muse, mutect2, varscan2
- ZNF500 | c.1350C>T p.T450= | Silent (SNP) | VAF 428/872 reads (49%) | catalogued as rs768459302; called by muse, mutect2
- ZNF729 | c.1377A>G p.P459= | Silent (SNP) | VAF 58/213 reads (27%) | catalogued as rs761245446, COSV62603962; called by muse, mutect2, varscan2
- ZNF879 | c.309C>A p.V103= | Silent (SNP) | VAF 84/142 reads (59%) | called by muse, mutect2, varscan2
- DLG1 | c.2005-776C>T | Intron (SNP) | VAF 17/154 reads (11%) | catalogued as rs776452461, COSV58391332; called by muse, mutect2, varscan2
- SDHAF2 | c.*335A>T | 3'UTR (SNP) | VAF 41/346 reads (12%) | called by muse, mutect2, varscan2
